Surgical pathology report (de-identified scan), TCGA case TCGA-06-0192, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0192-01B (Primary Tumor).

[page 1 of 2]
\\ Surgical Pathology Report

=====

CLINICAL HISTORY

Past history of [REDACTED] basal cell carcinoma resection x3; brain MRI shows contrast enhancing lesion within left occipital lobe.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Left parietal brain tumor
B: Left parietal brain tumor

PATHOLOGICAL DIAGNOSIS:

A B. Brain, left parietal lobe, biopsy: Glioblastoma multiforme,

COMMENT

This is a high grade glioma showing frequent mitotic figure, prominent vascular hyperplasia and large areas of tumor necrosis.

[REDACTED]

=====

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Received were paraffin curls labeled [REDACTED] [REDACTED] dated [REDACTED]

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in

[REDACTED]

[page 2 of 2]
[REDACTED]

the context of established procedures and/or diagnostic criteria.

TCGA-06-0192

[REDACTED]

INTRA-OPERATIVE CONSULTATION

A. Left parietal brain tumor: Glioma, 1 block, [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A. Multiple tissue fragments, 0.3 to 0.4 cm, all in A1, A2

B.

SPECIMEN: Left Parietal brain tumor.

FIXATIVE: None.

GENERAL: Received are multiple gray-white hemorrhagic irregular soft tissue fragments aggregating 4.5 x 3 x 0.5 cm.

SECTIONS: Entirely submitted in three cassettes.

[REDACTED]

ICD-9(s):

191.9 191.9

[REDACTED]

Histo Data

Part A: Left parietal brain tumor [REDACTED]

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
MGMT x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	

Part B: Left parietal brain tumor [REDACTED]

Taken:	Received:		
Stain/cnt	Block		Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
H/E x 1	3	[REDACTED]	

*** End of Report ***

[REDACTED]

Source: NCI Genomic Data Commons file f4e4f05e-551d-43ae-a582-61c312325055 (TCGA-06-0192.B6FF75E5-93AC-415E-B687-AE610F598564.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).